Somatic mutation profile of tumor specimen ALCH-B366-TTP1-A (aliquot ALCH-B366-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B366, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.6 years (21,041 days).
Specimen ALCH-B366-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5de4a38b-322a-4043-8ced-e4b87dbb216a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B366-NB1-A (Blood Derived Normal), aliquot ALCH-B366-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c337e9e-e4c9-4227-8f83-89c31c61aedd

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 3, Nonsense Mutation 3, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 48/474 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 76/496 reads (15%) | catalogued as rs1180309541, CM151372, COSV70341700; ClinVar: pathogenic; called by muse, varscan2
- DLGAP2 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 76/511 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV70093241; called by muse, mutect2, varscan2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 87/605 reads (14%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- FAM171A1 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65316901; called by muse, mutect2, varscan2
- FMN2 | c.2296C>G p.R766G | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100146631; called by muse, mutect2, varscan2
- LETM2 | c.1364C>T p.S455L (on ENST00000379957 / NM_001286819.2; = p.S360L on NM_144652.3) | Missense Mutation (SNP) | VAF 72/586 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1381986036; called by muse, mutect2, varscan2
- OR52E4 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs1272415148, COSV57625985; called by muse, mutect2
- PHF3 | c.2849T>C p.V950A | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs911567703; called by muse, varscan2
- PHF3 | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 73/587 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV50324011; called by muse, mutect2, varscan2
- PPP1R21 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs933306213; called by muse, mutect2
- RYR2 | c.12759G>T p.L4253F | Missense Mutation (SNP) | VAF 58/1248 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV63684386; called by muse, mutect2
- SIRPB1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs369732461, COSV53537626; called by muse, mutect2, varscan2
- TEPSIN | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs765023513; called by muse, mutect2, varscan2
- TTI2 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 103/603 reads (17%) | catalogued as COSV62452529; called by muse, mutect2, varscan2
- ANXA11 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.255); called by muse, mutect2
- EXO1 | c.2240C>G p.A747G | Missense Mutation (SNP) | VAF 36/571 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2
- FBN2 | c.8569C>T p.H2857Y | Missense Mutation (SNP) | VAF 40/776 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- FGA | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 28/533 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- ITPR2 | c.4703C>G p.S1568* | Nonsense Mutation (SNP) | VAF 69/281 reads (25%) | called by muse, mutect2, varscan2
- METTL14 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MPDZ | c.3931G>A p.D1311N | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR1N2 | c.635T>A p.V212D | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PCDHA6 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBMY1J | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- VPS13C | c.10684G>A p.A3562T (on ENST00000644861 / NM_020821.3; = p.A3519T on NM_017684.5) | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AFM | c.399G>A p.V133= | Silent (SNP) | VAF 79/485 reads (16%) | called by muse, mutect2, varscan2
- ASB4 | c.564G>A p.S188= | Silent (SNP) | VAF 144/394 reads (37%) | catalogued as COSV100367098, COSV57945702; called by muse, mutect2, varscan2
- CDH10 | c.1218A>G p.V406= | Silent (SNP) | VAF 124/318 reads (39%) | called by muse, mutect2, varscan2
- CPD | c.609C>T p.S203= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs747304806; called by muse, mutect2, varscan2
- DNM1 | c.1356A>G p.L452= | Silent (SNP) | VAF 44/356 reads (12%) | catalogued as rs756954152; called by muse, mutect2, varscan2
- OR2F2 | c.663C>A p.I221= | Silent (SNP) | VAF 54/499 reads (11%) | catalogued as rs375012448; called by muse, mutect2, varscan2
- ASCC1 | chr10:72216889 C>T | 5'Flank (SNP) | VAF 77/326 reads (24%) | called by muse, mutect2, varscan2
- CACNA1B | c.530+9247G>C | Intron (SNP) | VAF 153/486 reads (31%) | called by muse, mutect2, varscan2
- EYS | c.1767-7359G>A | Intron (SNP) | VAF 42/504 reads (8%) | catalogued as rs765095616, COSV65458889; called by muse, mutect2, varscan2
- NT5E | c.*28T>C | 3'UTR (SNP) | VAF 43/265 reads (16%) | called by muse, mutect2, varscan2
- TTC21B | c.151+39A>G | Intron (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
